Somatic mutation profile of tumor specimen BA2221D (aliquot aq-BA2221D) from BEATAML1.0 case 2529, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.2 years (24,894 days).
Specimen BA2221D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 92114109-b579-42f4-aa72-e7eb6fcec42c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2432D (Solid Tissue Normal), aliquot aq-BA2432D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc1309a4-47bc-4da7-bb00-dd6c28c5a577

The open-access MAF lists 17 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Intron 2, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP3K9 | c.2879G>T p.R960L (on ENST00000554752 / NM_001284230.1; = p.R974L on NM_033141.4) | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as COSV101173714; called by muse, mutect2
- WNT7B | c.847G>T p.A283S | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as COSV59752462; called by muse, mutect2
- ADGRG4 | c.7172C>A p.T2391K | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); called by muse, mutect2
- DDA1 | c.201C>A p.N67K | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.346); called by muse, mutect2
- GIMAP6 | c.373G>T p.A125S | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- GPR137 | c.1211C>A p.A404D | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.836); called by muse, mutect2
- NCAM2 | c.1382A>G p.E461G | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2
- PREP | c.178G>T p.A60S (on ENST00000369110; = p.A126S on NM_002726.5) | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.315); called by muse, mutect2
- SECISBP2 | c.5C>A p.A2E | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2
- STK40 | c.314G>T p.G105V | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- TKT | c.953G>T p.R318L | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2
- TTC9B | c.575G>T p.R192L | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.009); called by muse, mutect2
- ZNF749 | c.2295C>A p.S765R | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.046); called by muse, mutect2
- CRAMP1 | c.180C>A p.P60= | Silent (SNP) | VAF 3/19 reads (16%) | called by muse, mutect2
- UBE4A | c.2934A>G p.Q978= (on ENST00000252108 / NM_001204077.2; = p.Q985= on NM_004788.4) | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as rs782259280; called by muse, mutect2
- LTBP3 | c.2893+12G>T | Intron (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- SUPT20H | c.1592-172G>T | Intron (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2
